Somatic mutation profile of tumor specimen MMRF_1539_1_BM_CD138pos (aliquot MMRF_1539_1_BM_CD138pos_T1_KBS5U_L03507) from MMRF case MMRF_1539, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.5 years (20,993 days).
Specimen MMRF_1539_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a69bafd-e379-419a-87e2-f3a2a5910f37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1539_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1539_1_PB_Whole_C2_KBS5U_L03511; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51afebd0-1599-454d-a954-d80f3186e324

The open-access MAF lists 81 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 18, Silent 12, Intron 8, 5'UTR 2, RNA 2, Splice Site 2, 3'Flank 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTPBP1 | c.2678C>T p.T893I (on ENST00000357081 / NM_001330701.2; = p.T853I on NM_015239.2) | Missense Mutation (SNP) | VAF 114/241 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61268110; called by muse, mutect2, varscan2
- CABYR | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs762207878; called by muse, mutect2, varscan2
- HSPA12A | c.1856A>T p.K619M | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV65020620; called by muse, mutect2, varscan2
- IGHD6-25 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 88/88 reads (100%) | catalogued as rs577590165; called by muse, varscan2
- IGKJ3 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 126/126 reads (100%) | catalogued as rs188533155; called by muse, varscan2
- IGLV3-25 | c.149A>C p.Y50S | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as rs373673041; called by muse, mutect2, varscan2
- LRFN5 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 104/214 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1224152760, COSV99984449; called by muse, mutect2, varscan2
- MAMDC2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774754440; called by muse, mutect2, varscan2
- MLC1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.176); catalogued as rs529062080; called by muse, mutect2, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- RBM26 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs867475763, COSV57395025; called by muse, mutect2, varscan2
- SAMD9 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV66074557, COSV66076449; called by muse, mutect2
- SHANK2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.176); catalogued as rs199629765, COSV53588648; called by muse, mutect2, varscan2
- SIAE | c.651C>G p.S217R | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs901413096; called by muse, mutect2, varscan2
- SNAI3 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs746301482; called by muse, mutect2, varscan2
- ADGRL3 | c.2431G>T p.V811L (on ENST00000506720 / NM_001322402.2; = p.V743L on NM_015236.6) | Missense Mutation (SNP) | VAF 153/304 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKH | c.1003T>A p.S335T | Missense Mutation (SNP) | VAF 106/182 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- APBA2 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CACNB3 | c.991-2A>G p.X331_splice | Splice Site (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ELF1 | c.1763A>T p.Q588L | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); called by muse, mutect2
- GLRB | c.611T>C p.F204S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GNAS | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 101/217 reads (47%) | called by muse, mutect2, varscan2
- HECW2 | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- IGLV3-21 | c.-134-1G>C | Splice Site (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- KLK11 | c.236G>A p.C79Y (on ENST00000594768 / NM_144947.3; = p.C47Y on NM_006853.3) | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTIF2 | c.104A>C p.H35P | Missense Mutation (SNP) | VAF 185/354 reads (52%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEURL1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NEURL4 | c.3796G>T p.G1266W | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN1 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PEX6 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 86/164 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PHOSPHO2 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 126/258 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- PKHD1 | c.2447T>C p.L816P | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RANBP2 | c.8938A>G p.K2980E | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SARS1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TMEM39A | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP14 | c.1326T>G p.H442Q | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM205A | c.42C>T p.P14= | Silent (SNP) | VAF 111/250 reads (44%) | catalogued as rs1192784352; called by muse, mutect2, varscan2
- FREM2 | c.675C>T p.G225= | Silent (SNP) | VAF 55/104 reads (53%) | catalogued as COSV54831126; called by muse, mutect2, varscan2
- GAL3ST1 | c.222G>A p.P74= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV58892434; called by muse, mutect2
- GRM4 | c.576C>T p.Y192= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as rs368672368; called by muse, mutect2, varscan2
- NEK11 | c.351C>T p.D117= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs148912275; called by muse, mutect2, varscan2
- PADI2 | c.1734C>T p.D578= | Silent (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- SEC16B | c.2613C>T p.S871= | Silent (SNP) | VAF 61/139 reads (44%) | catalogued as rs373528898; called by muse, mutect2
- SMR3B | c.45G>A p.A15= | Silent (SNP) | VAF 66/172 reads (38%) | catalogued as rs200141400, COSV100513317; called by muse, mutect2, varscan2
- THSD7B | c.357C>T p.Y119= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs1455127441, COSV55663354; called by muse, mutect2, varscan2
- VNN1 | c.1524A>G p.V508= | Silent (SNP) | VAF 61/104 reads (59%) | called by muse, varscan2
- ZNF568 | c.1842T>C p.T614= | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as rs937222884; called by muse, mutect2, varscan2
- ZNF600 | c.444A>G p.L148= | Silent (SNP) | VAF 93/193 reads (48%) | called by muse, mutect2, varscan2
- ACTN4 | c.*401T>C | 3'UTR (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.*710A>C | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- ANKRD17 | c.*767T>G | 3'UTR (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.*121C>G | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- BARHL2 | c.-24G>A | 5'UTR (SNP) | VAF 84/181 reads (46%) | catalogued as rs200060831; called by muse, mutect2, varscan2
- CER1 | c.*188C>G | 3'UTR (SNP) | VAF 28/48 reads (58%) | catalogued as COSV66603724; called by muse, mutect2, varscan2
- CHST13 | c.*530T>C | 3'UTR (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- COLEC11 | c.130+1625G>A | Intron (SNP) | VAF 132/279 reads (47%) | called by muse, mutect2, varscan2
- CTRB2 | c.53-91A>G | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2
- DNAJB2 | c.65+30T>G | Intron (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- DNM1L | c.-58C>A | 5'UTR (SNP) | VAF 50/93 reads (54%) | called by muse, mutect2, varscan2
- EDN3 | chr20:59300543 T>C | 5'Flank (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- FAM102B | c.*3179A>G | 3'UTR (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- FAM131B | chr7:143353540 T>A | 3'Flank (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- GAB2 | c.*2936G>A | 3'UTR (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- GALNT1 | c.*1418G>A | 3'UTR (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- GP1BA | c.*113T>C | 3'UTR (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
- IRX3 | c.*66A>G | 3'UTR (SNP) | VAF 111/270 reads (41%) | called by muse, mutect2, varscan2
- KIR3DP1 | n.368del | RNA (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- KLF4 | c.*243G>A | 3'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- KLK3 | c.631-430A>T | Intron (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- MSL3P1 | n.1138T>C | RNA (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- MTREX | c.3077-854C>G | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as rs1023515612; called by muse, mutect2, varscan2
- MYOM3 | c.3423+453G>A | Intron (SNP) | VAF 27/55 reads (49%) | catalogued as rs980876671; called by muse, mutect2, varscan2
- NTRK2 | c.1397-54969T>A | Intron (SNP) | VAF 39/92 reads (42%) | catalogued as rs1253883193; called by muse, mutect2, varscan2
- PCDHB12 | c.*307T>C | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- PI15 | c.*2451dup | 3'UTR (INS) | VAF 29/67 reads (43%) | called by mutect2, varscan2
- PLD6 | c.*1674G>A | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- TAF5L | c.972+1541G>T | Intron (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- TMEM225B | c.*76C>G | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1878A>G | 3'UTR (SNP) | VAF 70/156 reads (45%) | called by muse, mutect2, varscan2
- YWHAQ | c.*163G>C | 3'UTR (SNP) | VAF 146/304 reads (48%) | called by muse, mutect2, varscan2
